Somatic mutation profile of tumor specimen TARGET-30-PATNCI-01A (aliquot TARGET-30-PATNCI-01A-01D) from TARGET case TARGET-30-PATNCI, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 5.6 years (2,031 days).
Specimen TARGET-30-PATNCI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 020fa432-fe26-4b43-adee-1ba088fa3c6f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATNCI-10A (Blood Derived Normal), aliquot TARGET-30-PATNCI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bd0cff4-bf03-40cf-8de6-550a9caef4fe

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SIGLEC7 | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as COSV58318741; called by muse, mutect2, varscan2
- PHOX2B | c.866dup p.P290Sfs*70 | Frame Shift Ins (INS) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
